Somatic mutation profile of tumor specimen TCGA-SP-A6QF-01A (aliquot TCGA-SP-A6QF-01A-12D-A35I-08) from TCGA case TCGA-SP-A6QF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 48.7 years (17,795 days).
Specimen TCGA-SP-A6QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e94db97b-0284-4340-901b-b712d18f9163.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QF-10A (Blood Derived Normal), aliquot TCGA-SP-A6QF-10A-21D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e27c14d5-8068-496f-a4d7-24b62e230b83

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1L2 | c.2024T>C p.I675T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs942899114, COSV51553649; called by muse, mutect2
- COPS5 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63474896; called by muse, mutect2
- ETV6 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1333027552; called by muse, mutect2
- C2CD3 | c.5291C>G p.P1764R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG1 | c.4486G>T p.G1496C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); called by muse, mutect2
- RBL2 | c.475del p.S159Lfs*3 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- CAPN9 | c.1083C>G p.G361= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- CEMIP | c.2712C>T p.S904= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs375813681; called by muse, mutect2, varscan2
- FTO | c.279G>A p.P93= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs746892119, COSV67110997; called by muse, mutect2, varscan2
- RASSF1 | c.678A>T p.A226= (on ENST00000357043 / NM_170714.2; = p.A222= on NM_007182.5) | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.1045C>T p.L349= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- SPTB | c.1998C>G p.G666= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
